Gene-level copy-number profile of tumor specimen C3L-02616-05 from CPTAC case C3L-02616, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 63.7 years (23,275 days).
Specimen C3L-02616-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14777ca7-9d37-42b1-8e5f-9cbb6e853073.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02616-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/6915c46a-829c-4c2d-be64-f3535b9237d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 67; copy number 2: 21,379; copy number 3: 17,824; copy number 4: 13,203; copy number 5: 3,543; copy number 6: 2,097; copy number 7: 186; copy number 8: 62; copy number 9: 7; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,084,233, 7 genes (within-gene range 0–1): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880.
- chr13:48,232,612–48,771,827, 15 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,896 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,817,767, 178 genes, copy number 5 (broad region; genes not listed).
- chr1:37,154,761–45,781,957, 296 genes, copy number 5 (broad region; genes not listed).
- chr2:34,692,290–71,686,768, 612 genes, copy number 5 (broad region; genes not listed).
- chr2:95,574,901–96,870,757, 43 genes, copy number 5: TRIM51JP, AC009237.16, AC009237.4, TRIM43, AC009237.7, AC009237.13, AC009237.12, UBTFL3, AC009237.17, AC009237.6, AC009237.9, AC008268.1, GPAT2P1, LINC00342, ANKRD36C, RN7SL210P, FAHD2CP, GPAT2, ADRA2B, ASTL, DUSP2, AC012307.1, STARD7, STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C.
- chr2:97,113,153–98,594,392, 31 genes, copy number 5: ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A.
- chr2:108,894,471–109,985,124, 20 genes, copy number 5 (within-gene range 2–5): EDAR, Metazoa_SRP, SH3RF3-AS1, SH3RF3, MIR4265, SNRPGP9, MIR4266, SEPTIN10, RPL37P12, AC011753.2, SOWAHC, AC011753.1, BMS1P19, SRSF3P6, RPL22P11, RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5.
- chr3:96,814,581–166,862,110, 1,128 genes, copy number 5–7 (broad region; genes not listed).
- chr3:169,083,499–170,860,993, 43 genes, copy number 5 (within-gene range 2–5): MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5.
- chr3:196,214,222–198,123,232, 73 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr4:53,377,641–55,636,698, 48 genes, copy number 5: FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU.
- chr5:58,198–56,382,075, 787 genes, copy number 6 (broad region; genes not listed).
- chr7:37,032–64,470,653, 1,123 genes, copy number 6 (broad region; genes not listed).
- chr7:64,870,172–66,545,066, 55 genes, copy number 5–6 (within-gene range 2–8): ZNF273, AC073349.1, VN1R42P, MTDHP1, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3, AC114501.1, AC114501.2, AC104057.1, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3.
- chr9:61,330,717–61,582,675, 3 genes, copy number 5: CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:61,642,383–61,662,690, 2 genes, copy number 12: Y_RNA, AL935212.1.
- chr11:125,625,665–127,003,460, 37 genes, copy number 5 (within-gene range 4–5): CHEK1, RNU2-35P, ACRV1, PATE1, PATE2, PATE3, PATE4, AP000842.3, HYLS1, PUS3, AP000842.2, DDX25, AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3, KIRREL3, KIRREL3-AS1, AP001783.1.
- chr12:113,462,033–113,773,726, 3 genes, copy number 5: LHX5, LHX5-AS1, LINC01234.
- chr13:19,633,659–19,783,019, 3 genes, copy number 6 (within-gene range 3–6): MPHOSPH8, PSPC1-AS2, PSPC1.
- chr13:27,402,476–28,495,145, 25 genes, copy number 5–6: RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1.
- chr13:28,820,348–47,459,234, 306 genes, copy number 5–8 (broad region; genes not listed).
- chr13:51,452,364–51,554,678, 1 gene, copy number 7 (within-gene range 3–7): INTS6-AS1.
- chr13:51,469,753–52,821,018, 44 genes, copy number 7: RN7SL320P, SNRPGP11, MIR4703, RNU6-65P, WDFY2, RNY1P6, RN7SL413P, ATP5PBP1, AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70, CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26.
- chr13:72,782,133–79,166,885, 83 genes, copy number 5–6 (broad region; genes not listed).
- chr13:83,298,071–93,227,317, 79 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr13:101,710,804–102,402,457, 1 gene, copy number 6 (within-gene range 3–6): FGF14.
- chr13:101,778,884–104,815,069, 30 genes, copy number 6: RNU1-24P, HMGB3P7, MIR2681, LIPT1P1, RNY1P2, MIR4705, RPL39P29, FGF14-IT1, AL356266.1, FGF14-AS1, FGF14-AS2, LINC00555, AL158063.1, TPP2, METTL21C, CCDC168, LINC00283, AL157769.1, TEX30, POGLUT2, BIVM-ERCC5, BIVM, ERCC5, METTL21EP, AL137246.1, AL137246.2, SLC10A2, LINC01309, ATP6V1G1P7, RPL7P45.
- chr13:105,897,523–111,901,264, 79 genes, copy number 6–7 (broad region; genes not listed).
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr20:13,368,291–13,996,443, 7 genes, copy number 5 (within-gene range 3–5): AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P.
- chr20:33,965,162–64,327,972, 754 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
